CMI case ASCProject_0165 — CMI-ASC: Count Me In (CMI): The Angiosarcoma (ASC) Project
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/ad315ed1-b656-44f0-9c83-f426056392f3

Demographics
Sex at birth: male; Race: other; Ethnicity: not hispanic or latino.

Diagnoses (1)
1. Angiosarcoma: Tissue or organ of origin: Skin of scalp and neck; Site of resection or biopsy: Skin of scalp and neck; Age at diagnosis: 62.5 years (22,836 days).

Biospecimens (2 samples)
- Sample ASCProject_0165_BLOOD_BC: Sample type: DNA; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood.
- Sample ASCProject_0165_T2_WES: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Scalp; Preservation method: FFPE.
